Surgical pathology report (de-identified scan), TCGA case TCGA-95-8494, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Emory, specimen TCGA-95-8494-01A (Primary Tumor).

[page 1 of 4]
Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

* Final Report *

APRPT (Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LUNG, RIGHT MIDDLE LOBE, LOBECTOMY:

- INVASIVE ADENOCARCINOMA (SEE SYNOPTIC).
- ELASTIC STAIN SHOWS INVASION INTO BUT NOT THROUGH PLEURAL ELASTICA.

B. LYMPH NODE, 10 R, BIOPSY:

- FRAGMENT OF LYMPH NODE, NO TUMOR SEEN.

C. LYMPH NODE, 11 R, BIOPSY:

- FRAGMENTS OF LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA.

D. LYMPH NODE, 7 R, BIOPSY:

- INVASIVE ADENOCARCINOMA; AT LEAST SOME OF THE TUMOR INVOLVES LUNG, AND NO DEFINITE LYMPH NODE IS SEEN.

Printed by:

Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
Anat Path Reports

* Final Report *

E. LYMPH NODE, 2 R, BIOPSY:

- 8 CROSS SECTIONS OF LYMPH NODE, NO TUMOR SEEN.

F. LYMPH NODE, 4 R, BIOPSY:

- FRAGMENTS OF LYMPH NODE, NO TUMOR SEEN.

Synoptic Worksheet

A. Right middle lobe lung; freeze bronchial margins:

Specimen:	Lobe(s) of lung: Right middle
Procedure:	Lobectomy
Specimen Integrity:	Intact
Specimen Laterality:	Right
Tumor Site:	Middle lobe
Tumor Focality:	Unifocal
Histologic Type:	Solid adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 4.5 cm
Visceral Pleura Invasion:	Present
Tumor Extension:	Not applicable
Bronchial Margin:	Uninvolved by invasive carcinoma Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Not applicable
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 37 mm Margin closest to invasive carcinoma: Bronchial
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Indeterminate
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Anat Path Reports

* Final Report *

Regional Lymph Nodes (pN):

Distant Metastasis (pM):

Additional Pathologic Findings:

following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung

pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, and intrapulmonary nodes, including involvement by direct extension
Nodes examined: 5

Nodes involved: 1

Not applicable

Other: Obstructive pneumonitis

Clinical History

Pulmonary mass. Right VATS. Lobectomy.

Specimen(s) Received

A: Right middle lobe lung; freeze bronchial margins

B: 10R lymph node

C: 11R lymph node

D: 7R lymph node

E: 2R lymph node

F: 4R lymph node

Gross Description

The specimen is received in 6 parts each labeled with patient name and hospital number.

Specimen A. is received fresh and labeled as "right middle lobe lung, free bronchial margins". The specimen consists of a stapled purple pink lobe of lung which weighs 151 g and measures 13.5x9x3.6 cm. The bronchial margin is removed for frozen section evaluation. The frozen section residual is submitted as B1FS. The vascular margins are identified. There are no hilar nodes noted. Within the parenchyma there is an elongated to irregular grey firm tumor measuring 4.5x4x3.4 cm. The tumor bulges the overlying pleura which is inked blue. The tumor is 3.7 cm from the bronchial margin. The parenchyma shows areas of emphysema and congestion. Sections are submitted in 8 cassettes.

Code for microscopic

A1 FS: Bronchial margin

A2: Vascular margins

A3: Tumor to pleura

A4-A6: Tumor to normal lung

A7: Emphysema

A8: Congestion

Specimen B. is received in formalin labeled "10 R. lymph node". The specimen consists of an ovoid gray soft 0.9 cm lymph node.

[page 4 of 4]
Anat Path Reports

* Final Report *

The specimen is submitted in toto in one cassette.

Specimen C. is received in formalin labeled as "11 R Lymph Node". The specimen consists of multiple irregular gray-tan slightly firm portions of lymph node measuring 1.7 cm in aggregate. The specimen is submitted in toto in one cassette.

Specimen D. is received in formalin labeled as "7 R Lymph Node". The specimen consists of a single ovoid gray 1.2 cm lymph node. The specimen is entirely submitted in one cassette.

Specimen E. is received in formalin labeled as "2 R Lymph Node". The specimen consists of multiple ovoid to irregular portions of tan lymph node and fat measuring 2.3 cm in aggregate. The specimen is submitted in toto in one cassette.

Specimen F. is received in formalin labeled as "4 R lymph node". The specimen consists of multiple ovoid tan portions of lymph node with yellow fat measuring 2.5 cm in aggregate. The specimen is submitted in toto in one cassette.

Intraoperative Consult Diagnosis

A1FS: LUNG, RIGHT MIDDLE LOBE, BRONCHIAL MARGIN (FROZEN SECTION): FREE OF TUMOR

Frozen section results were communicated to the surgical team and were repeated back by

at

Microscopic Description

Microscopic examination performed.

Source: NCI Genomic Data Commons file b6b0c9b2-a6ce-4527-90ab-b6f0f8fedd9c (TCGA-95-8494.978929C4-0D93-4192-9A72-22047960CFBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).